TCGA case TCGA-TS-A7P6 — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: University of Pennsylvania. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74f63637-cc7c-4539-a57e-783c8f62fb95

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Dead; Days to death: 283 days.

Diagnoses (1)
1. Epithelioid mesothelioma, malignant: ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 61.2 years (22,338 days); Year of diagnosis: 2011; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: HPPH; Days to treatment start: 24 days; Days to treatment end: 27 days; Clinical trial indicator: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 283.

Exposures
- Occupation type: Ship and Aircraft Controllers and Technicians.
- Exposure type: Asbestos.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-TS-A7P6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 490 mg.
  Slide TCGA-TS-A7P6-01A-02-TSB: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample TCGA-TS-A7P6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-TS-A7P6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: Operations Instructor, Navy Shipyard.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- Drug treatment: Pharmaceutical therapy drug name: 2-[1-hexyloxyethyl]-2-devinyl pyropheophorbide-alpha (HPPH or Photochlor).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 283 days; disease-specific survival: event status not recorded, 283 days; progression-free interval: no event (censored), 283 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-TS-A7P6-01A-21D-A34B-01): tumor purity 0.66, ploidy 1.66, whole-genome doublings 0.
